Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GJ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GJ-06A (Metastatic).

** Case imported from
** For cases prior to

The format of this report does not match the original case. **
the section "SPECIMEN" may have been added. **

DIAGNOSIS

(A) JEJUNUM:

METASTATIC MALIGNANT MELANOMA (THREE TUMOR NODULES), RESECTION
MARGINS FREE OF TUMOR.

Nine mesenteric lymph nodes, no evidence of metastatic disease.

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) JEJUNUM - Two segments of small bowel. The longer one is 17.0 cm in length and the shorter one is 2.3 cm in length.

The longer segment of bowel contains three separate tumor nodules, all of which involve the mucosa and full thickness of the muscle wall. The srosal surface over the two larger nodules (#1 and #2) is irregular. The closest margin is 1.0 cm (from nodule #3). The opposite margin is 2.0 cm from the closest tumor nodule (#2). The tumor nodule measurements are as follows: #1 is 3.0 x 3.0 x 1.5 cm; #2 is 2.5 x 1.5 x 1.0 cm; and #3 is 2.5 x 1.2 x 1.0 cm.

The remaining part of the intestine is unremarkable. The smaller segment of intestine is grossly unremarkable.

INK CODE: Black - resection margin closest to the first tumor.

SECTION CODE: A1-A2, one lymph node; A3, one lymph node; A4-A10, one lymph node, bisected, in each cassette; A11, resection margin close to tumor #2 en face; A12-A13, resection margin and tumor #3 perpendicular; A14, from the first tumor; A15-A19, the largest tumor #1 (the A20, A21, second tumor; A22, mucosal hemorrhage and unremarkable mucosa; A23, second segment of intestine.

SNOMED CODES

M-87206 T-58000

-----END OF REPORT-----

ICD.O-3

Melanoma NOS 8720/3

Site ^{CCCF} Small intestine NOS C17.9

path Jejunum C17.1
path 11/27/13

Source: NCI Genomic Data Commons file 36cf641d-8071-4325-9df4-34a8e7a09d3b (TCGA-D3-A8GJ.6DCA5697-F731-48CA-803B-31CD5E374E45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).